Gene-level copy-number profile of specimen HCM-BROD-0235-C16-85B from HCMI case HCM-BROD-0235-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.7 years (18,528 days).
Specimen HCM-BROD-0235-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 62de4d79-55a3-4b92-bc2d-d9d1baaaae3e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0235-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/a4ee1467-fc99-4811-85bd-cf7761df7231

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 256; copy number 2: 8,902; copy number 3: 24,463; copy number 4: 19,024; copy number 5: 5,658; copy number 6: 85; copy number 7: 103; copy number 8: 13; copy number 9: 33; copy number 10: 25; copy number 12: 238; copy number 13: 60; copy number 16: 28; copy number 35: 7; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 508 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:84,528,122–86,217,733, 13 genes, copy number 7–9: RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr7:89,443,946–93,574,730, 61 genes, copy number 8–13 (broad region; genes not listed).
- chr7:93,890,913–102,283,958, 238 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr8:122,485,194–122,733,804, 1 gene, copy number 8 (within-gene range 5–8): LINC01151.
- chr8:122,671,291–124,260,752, 48 genes, copy number 8–10: AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P.
- chr8:124,450,820–124,474,582, 2 genes, copy number 7: TRMT12, RNF139-AS1.
- chr8:124,811,042–125,901,054, 19 genes, copy number 7–9: AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.1, RNU6-442P.
- chr8:126,556,323–127,419,050, 1 gene, copy number 7 (within-gene range 5–7): PCAT1.
- chr8:127,072,694–127,482,139, 6 genes, copy number 7 (within-gene range 5–7): CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B.
- chr8:128,150,116–128,564,679, 3 genes, copy number 7: MIR1208, RN7SKP226, LINC00824.
- chr8:131,308,545–131,712,980, 3 genes, copy number 7: AC104257.1, SNORA72, AC060788.1.
- chr8:132,866,958–133,134,903, 5 genes, copy number 7: TG, AF305872.1, SLA, MIR7848, PTCSC1.
- chr8:133,573,183–133,756,646, 5 genes, copy number 7: AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49.
- chr10:38,601,418–38,617,344, 2 genes, copy number 7: ABCD1P2, AL133173.2.
- chr19:13,206,442–14,213,323, 36 genes, copy number 16–37 (within-gene range 3–37): CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P.
- chr19:23,492,428–27,984,984, 36 genes, copy number 7–8 (within-gene range 6–8): ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr22:15,282,557–15,829,984, 29 genes, copy number 7: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8.

Autosomal genes at a single copy (total copy number 1): 256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
